Somatic mutation profile of tumor specimen TCGA-AA-3842-01A (aliquot TCGA-AA-3842-01A-01W-0995-10) from TCGA case TCGA-AA-3842, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 51.6 years (18,842 days).
Specimen TCGA-AA-3842-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb072e4f-e865-4cf9-b75d-230cef00f715.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3842-10A (Blood Derived Normal), aliquot TCGA-AA-3842-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13d7a3bc-367f-4d6b-846f-5db025b00826

The open-access MAF lists 103 somatic variants for this specimen: 70 protein-altering or splice-affecting, 33 silent.
By variant classification: Missense Mutation 62, Silent 33, Nonsense Mutation 4, Splice Site 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAD1 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs200229076, COSV56642519, COSV56644466; called by muse, mutect2
- ADGRL2 | c.2587G>A p.A863T (on ENST00000370717 / NM_001366005.1; = p.A850T on NM_012302.4) | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.192); catalogued as COSV99588095; called by muse, mutect2
- AMPH | c.296G>C p.G99A | Missense Mutation (SNP) | VAF 29/433 reads (7%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.562); catalogued as COSV100341599; called by muse, mutect2
- ARNTL | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 48/851 reads (6%) | catalogued as COSV62986699; called by muse, mutect2
- ATP1A1 | c.2087A>G p.Q696R | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55192016; called by muse, mutect2, varscan2
- BOP1 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 344/395 reads (87%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100265968; called by muse, varscan2
- CDH12 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 442/1260 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765565044, COSV101202350, COSV66397071; called by muse, varscan2
- CLDN8 | c.650G>T p.S217I | Missense Mutation (SNP) | VAF 111/919 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV99729777; called by muse, mutect2, varscan2
- DCC | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT tolerated (0.19); PolyPhen benign (0.101); catalogued as COSV59085103; called by muse, mutect2, varscan2
- DMXL2 | c.5437G>A p.D1813N | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as COSV99196180; called by muse, mutect2, varscan2
- DNAH5 | c.6128C>T p.S2043L | Missense Mutation (SNP) | VAF 86/185 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172080760, COSV99447824; called by muse, mutect2, varscan2
- DOCK8 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 90/367 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66634410; called by muse, mutect2, varscan2
- DPY19L3 | c.1992G>A p.M664I | Missense Mutation (SNP) | VAF 70/740 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV60477774; called by muse, mutect2
- ERICH3 | c.2516C>A p.A839E | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV100443919; called by muse, mutect2, varscan2
- FAM155A | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 179/1163 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.178); catalogued as COSV65567357; called by muse, mutect2, varscan2
- GJD2 | c.605A>T p.Q202L | Missense Mutation (SNP) | VAF 21/269 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV99290660; called by muse, mutect2
- GNAI1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 311/757 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs910988907, COSV100650337, COSV63522913; called by muse, mutect2, varscan2
- GNAO1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as CM161438, COSV52615065; called by muse, mutect2, varscan2
- GRIN2D | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV54379603; called by muse, mutect2, varscan2
- HAAO | c.775G>T p.G259W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV54311458; called by muse, mutect2, varscan2
- HIPK2 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 149/345 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100702056; called by muse, mutect2, varscan2
- HOMER2 | c.637A>G p.R213G (on ENST00000304231 / NM_199330.3; = p.R202G on NM_004839.4) | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV100420283; called by muse, mutect2, varscan2
- IGFL3 | c.304A>T p.M102L | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58242888; called by muse, mutect2, varscan2
- ISL1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100045251, COSV57935650; called by muse, mutect2, varscan2
- KANSL1 | c.2722A>C p.I908L (on ENST00000574590 / NM_001193465.2; = p.I909L on NM_015443.4) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV99290202, COSV99291033; called by muse, mutect2
- KIAA1217 | c.5036C>T p.T1679I | Missense Mutation (SNP) | VAF 148/381 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs757892982, COSV100286414; called by muse, mutect2, varscan2
- KLF12 | c.250T>G p.L84V | Missense Mutation (SNP) | VAF 36/518 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100888445; called by muse, mutect2
- LILRB5 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs765220698, COSV100300233; called by muse, mutect2, varscan2
- LRRC4B | c.1682C>T p.T561M | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV65349702; called by muse, mutect2, varscan2
- MAN1C1 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 271/567 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760511398, COSV99848098; called by muse, mutect2, varscan2
- MDN1 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs759337910, COSV101021065; called by muse, mutect2, varscan2
- ME1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 467/955 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775383665, COSV100866435; called by muse, mutect2, varscan2
- MYBPH | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201112460; called by muse, mutect2, varscan2
- NIM1K | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 291/459 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as rs768600358, COSV58145814; called by muse, mutect2, varscan2
- NLGN4Y | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 77/108 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.366); catalogued as COSV59297058; called by muse, mutect2, varscan2
- NOM1 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 98/252 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs777877933, COSV99315285; called by muse, mutect2, varscan2
- NPR1 | c.2660C>T p.A887V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs758216180, COSV64118084; called by muse, mutect2, varscan2
- NTM | c.548A>G p.D183G | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as COSV100868134; called by muse, mutect2
- OPRK1 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55571363; called by muse, mutect2, varscan2
- OR4D10 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 63/1252 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101597003; called by muse, mutect2
- OR8G1 | c.56A>C p.E19A | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV100422342; called by muse, mutect2, varscan2
- PCDH9 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as rs147427572; called by muse, mutect2, varscan2
- PDZD11 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 309/338 reads (91%) | catalogued as rs1482909841, COSV52104064; called by muse, mutect2, varscan2
- PPP1R12B | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as rs369793804; called by muse, mutect2, varscan2
- PYHIN1 | c.784A>G p.K262E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100932340; called by muse, mutect2, varscan2
- RAB3IL1 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 79/127 reads (62%) | catalogued as rs1279112424, COSV57117894; called by muse, mutect2, varscan2
- RXFP1 | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs771654308, COSV100313662; called by muse, mutect2, varscan2
- RXFP2 | c.918T>A p.N306K | Missense Mutation (SNP) | VAF 167/420 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53635883; called by muse, mutect2, varscan2
- SDK1 | c.2312C>G p.P771R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV101269128; called by muse, mutect2, varscan2
- SFMBT2 | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 134/215 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145231461; called by muse, mutect2, varscan2
- SFTPD | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs548930059, COSV64853075; called by muse, mutect2, varscan2
- SLC35A1 | c.758C>A p.A253E | Missense Mutation (SNP) | VAF 95/459 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV65780269; called by muse, mutect2, varscan2
- SMAD2 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 42/175 reads (24%) | catalogued as COSV50994183; called by muse, mutect2, varscan2
- SNTG1 | c.239T>G p.I80S | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV52451093; called by muse, mutect2
- SYNPO2 | c.3680G>T p.R1227I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as COSV61112855; called by muse, mutect2, varscan2
- TAF1 | c.4759-1G>A p.X1587_splice (on ENST00000373790 / NM_138923.4; = p.X1608_splice on NM_004606.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 186/222 reads (84%) | catalogued as COSV99335288; called by muse, mutect2, varscan2
- TCEA2 | c.820-1G>T p.X274_splice | Splice Site (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100180663; called by muse, varscan2
- THBS2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759210002, COSV64677175; called by muse, mutect2, varscan2
- TP53 | c.1004del p.R335Lfs*10 | Frame Shift Del (DEL) | VAF 23/31 reads (74%) | catalogued as COSV52822347, COSV52875617; called by mutect2, varscan2
- TPTE2 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55017949, COSV99691015; called by muse, mutect2
- USP24 | c.7706C>T p.A2569V | Missense Mutation (SNP) | VAF 343/716 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99599346; called by muse, mutect2, varscan2
- UTRN | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100839779; called by muse, mutect2
- VEGFC | c.277A>G p.N93D | Missense Mutation (SNP) | VAF 130/553 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99709672; called by muse, mutect2, varscan2
- VRTN | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs775926527, COSV56441332; called by muse, mutect2, varscan2
- VWF | c.4970T>C p.L1657P | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM137957, COSV99778626; called by muse, varscan2
- WDFY3 | c.4141C>T p.R1381W | Missense Mutation (SNP) | VAF 130/371 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99882944; called by muse, mutect2, varscan2
- ZNF37A | c.1259T>C p.F420S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100697323; called by muse, mutect2
- DENND6A | c.1433_1435del p.L478del | In Frame Del (DEL) | VAF 9/39 reads (23%) | called by pindel, varscan2
- IGKV1D-16 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2
- C1orf198 | c.681C>T p.P227= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as COSV64175696; called by muse, mutect2, varscan2
- CARD11 | c.1791C>T p.D597= | Silent (SNP) | VAF 70/227 reads (31%) | catalogued as rs764782588, COSV62755747; called by muse, varscan2
- CDK18 | c.1272G>A p.L424= (on ENST00000506784 / NM_212503.3; = p.L394= on NM_002596.4) | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV63727834; called by muse, varscan2
- DAPK1 | c.1593C>T p.A531= | Silent (SNP) | VAF 49/187 reads (26%) | catalogued as rs773562327, COSV63786623; called by muse, mutect2, varscan2
- DHRS3 | c.456C>T p.F152= | Silent (SNP) | VAF 14/151 reads (9%) | catalogued as COSV66108376; called by muse, varscan2
- DSEL | c.957G>A p.K319= | Silent (SNP) | VAF 38/61 reads (62%) | catalogued as rs1369518092, COSV100025426, COSV59492423; called by muse, mutect2, varscan2
- ELAVL4 | c.765C>T p.G255= | Silent (SNP) | VAF 121/388 reads (31%) | catalogued as rs761380670, COSV63916901; called by muse, mutect2, varscan2
- ERP29 | c.165C>T p.F55= | Silent (SNP) | VAF 102/412 reads (25%) | catalogued as rs753084104, COSV55673946; called by muse, mutect2, varscan2
- GRIA1 | c.1122C>T p.D374= | Silent (SNP) | VAF 297/522 reads (57%) | catalogued as rs140876127, COSV53592013; called by muse, mutect2, varscan2
- IGHV1-3 | c.282C>T p.S94= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as rs113102957; called by muse, mutect2, varscan2
- INCENP | c.1218G>A p.T406= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1389329008, COSV53916917; called by muse, mutect2
- LAMP3 | c.543C>T p.T181= | Silent (SNP) | VAF 690/1203 reads (57%) | catalogued as rs759259053, COSV55615311; called by mutect2, varscan2
- MASP1 | c.423C>T p.D141= | Silent (SNP) | VAF 41/183 reads (22%) | catalogued as rs764740497, COSV51459689; called by muse, mutect2, varscan2
- MAT1A | c.852G>A p.G284= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs920251779, COSV64746975; called by muse, mutect2, varscan2
- MYO9B | c.5475C>T p.L1825= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as COSV101261473; called by muse, mutect2, varscan2
- NLGN1 | c.1680G>A p.T560= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs747826638, COSV64323475; called by muse, mutect2, varscan2
- NOL4L | c.366C>T p.Y122= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as rs371387659; called by muse, mutect2, varscan2
- OR2T1 | c.696C>A p.G232= | Silent (SNP) | VAF 78/159 reads (49%) | catalogued as COSV63542248; called by muse, mutect2, varscan2
- PAK3 | c.1089C>A p.G363= (on ENST00000262836 / NM_001324328.2; = p.G348= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 2078/2622 reads (79%) | catalogued as COSV53276194; called by muse, mutect2, varscan2
- PCDHGA2 | c.1779G>A p.A593= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as rs147764693, COSV53968611; called by muse, mutect2, varscan2
- PDE10A | c.1146C>T p.I382= | Silent (SNP) | VAF 217/876 reads (25%) | catalogued as rs777212417, COSV100604909; called by muse, mutect2, varscan2
- PDLIM4 | c.447C>T p.G149= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99516802; called by muse, mutect2
- PSEN2 | c.792C>T p.L264= | Silent (SNP) | VAF 62/185 reads (34%) | catalogued as rs77875620, COSV60914754; called by muse, mutect2, varscan2
- PTPRT | c.1239G>A p.A413= | Silent (SNP) | VAF 62/533 reads (12%) | catalogued as rs200094311, COSV100626422, COSV100628481; called by muse, mutect2, varscan2
- RGS22 | c.3048T>C p.S1016= | Silent (SNP) | VAF 12/356 reads (3%) | catalogued as COSV100693138; called by muse, mutect2
- RP1 | c.4818A>T p.T1606= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV55119367; called by muse, mutect2, varscan2
- ST8SIA1 | c.60G>A p.A20= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1351103507, COSV53950573; called by muse, mutect2, varscan2
- TGIF2LY | c.102G>A p.S34= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV58291485; called by muse, mutect2, varscan2
- TLL1 | c.2310G>A p.K770= | Silent (SNP) | VAF 10/314 reads (3%) | catalogued as rs1321557747, COSV99286814; called by muse, mutect2
- TMEM132D | c.2919G>T p.L973= | Silent (SNP) | VAF 38/276 reads (14%) | catalogued as COSV67160783; called by muse, mutect2, varscan2
- ZNF135 | c.1824T>C p.C608= (on ENST00000313434 / NM_001289401.2; = p.C620= on NM_003436.4) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV57883121; called by muse, mutect2, varscan2
- ZNF439 | c.1311G>A p.P437= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs150203756, COSV58310614; called by muse, mutect2, varscan2
- ZNF530 | c.1002C>T p.H334= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV60531823; called by muse, mutect2, varscan2
